Gene-level copy-number profile of tumor specimen TCGA-PL-A8LZ-01A from TCGA case TCGA-PL-A8LZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 29.8 years (10,869 days).
Specimen TCGA-PL-A8LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0e185d4c-d0cd-4098-a9ce-0a0ead6ab508.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PL-A8LZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac4f2942-2da9-4a6e-8511-3cf9acaa0051

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,504; copy number 2: 28,306; copy number 3: 14,665; copy number 4: 8,769; copy number 5: 1,949; copy number 6: 920; copy number 7: 1,442; copy number 8: 708; copy number 10: 549.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PL-A8LZ-01A-31D-A36I-01): tumor purity 0.25, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,568 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–204,616,565, 1,617 genes, copy number 5–8 (broad region; genes not listed).
- chr1:204,707,320–215,621,807, 240 genes, copy number 7 (broad region; genes not listed).
- chr1:215,630,026–215,901,464, 2 genes, copy number 7: SNORD116, AL358452.1.
- chr2:5,549,780–6,375,422, 11 genes, copy number 7: AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158, AC017053.1, LINC01247.
- chr2:102,619,553–116,726,771, 283 genes, copy number 6 (broad region; genes not listed).
- chr3:142,407,657–198,222,513, 969 genes, copy number 5–10 (broad region; genes not listed).
- chr8:100,133,351–128,187,101, 388 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:141,117,278–145,066,685, 191 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 6–7 (broad region; genes not listed).
- chr10:44,712–14,878,686, 262 genes, copy number 7 (broad region; genes not listed).
- chr17:72,033,772–83,095,122, 453 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
